Somatic mutation profile of tumor specimen 0DHZS9 from CCDI case PBBRUP, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Undifferentiated sarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues, NOS; Age at diagnosis: 0.7 years (265 days).
Specimen 0DHZS9: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 30150bca-7800-4dd3-8605-463ba8b28239.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DHZRW (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4bc4f81b-b864-40ae-bc5f-c1da051a47e9

The open-access MAF lists 3 somatic variants for this specimen: 1 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Intron 2, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MIA2 | c.857C>T p.T286M | Missense Mutation (SNP) | VAF 90/1442 reads (6%) | SIFT tolerated (0.29); PolyPhen benign (0.027); catalogued as rs1429172343, COSV54499311, COSV99698415; called by muse, mutect2
- CCDC149 | c.63+17714C>A | Intron (SNP) | VAF 14/336 reads (4%) | catalogued as rs1341369251; called by muse, mutect2
- CCDC149 | c.63+17713T>G | Intron (SNP) | VAF 14/318 reads (4%) | called by muse, mutect2
